Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A17N, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A17N-01A (Primary Tumor).

[page 1 of 2]
1C5-0-3

Adenocarcinoma, Endometrioid, NOS

8380/3

12/19/10

Site Code: Endometrium C54.1

per

Surgical Pathology

DIAGNOSIS:

A. Abdomen, panniculectomy: Skin and subcutaneous tissue, 2020.0

grams, identified grossly. Gross exam only.

B. Uterus, bilateral ovaries, and fallopian tubes; hysterectomy and bilateral salpingo-oophorectomy: FIGO grade 2 (of 3) endometrial

adenocarcinoma, endometrioid type, circumferentially involving the

endometrial cavity. The tumor is confined to the endometrium. The

tumor does not involve the endocervix. The myometrium shows

extensive adenomyosis forming a 4.5 x 4.1 x 3.1 cm well-circumscribed trabeculated myometrial nodule. The bilateral

ovaries and fallopian tubes are without diagnostic abnormality.

GROSS DESCRIPTION:

A. Received fresh labeled "abdominal pannus" is a 2020.0 gram portion of skin and subcutaneous tissue without umbilicus. No

lesions identified. Gross examination only.

B. Received fresh labeled "uterus, right and left fallopian tubes

and ovaries" is a 145.0 gram uterus with attached bilateral tubes

and ovaries and an unremarkable cervix. The uterine serosa is

smooth. The endometrial cavity shows thickening. There are no

leiomyomas. There is a 4.5 x 4.1 x 3.1 cm well-circumscribed

trabeculated myometrial nodule. There is a 2.7 x 1.2 x 0.8 cm right

ovary with a smooth outer surface and a solid cut surface with a 8.5

[page 2 of 2]
x 0.4 cm right fallopian tube. There is a 2.9 x 1.2 x 1.0 cm left ovary with a smooth outer surface and a solid cut surface with a 6.5 x 0.5 cm left fallopian tube. Representative sections submitted.

BLOCK SUMMARY:

Part A: Abdominal Pannus

Part B: Uterus, right & left fallopian tubes & ovaries

- 1 Endometrial cavity-1
- 2 Endometrial cavity-2
- 3 Endometrial cavity-3
- 4 Endometrial cavity-4
- 5 Rt fallopian tube & ovary
- 6 Lt fallopian tube & ovary
- 7 Lower uterine segment
- 8 Cervix

ICD-9 Discrepancy		/

Source: NCI Genomic Data Commons file 4561f70a-7086-4987-98b8-e21656591452 (TCGA-D1-A17N.AD892375-1A50-4D9E-8235-A9A495C35B97.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).